Somatic mutation profile of tumor specimen MMRF_2573_1_BM_CD138pos (aliquot MMRF_2573_1_BM_CD138pos_T1_KHS5U_L12909) from MMRF case MMRF_2573, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.7 years (26,564 days).
Specimen MMRF_2573_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a771f934-4e32-47d5-8282-8cdb5edf54d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2573_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2573_1_PB_Whole_C3_KHS5U_L12910; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79d4f2c7-6bfe-41d2-b17b-53cf36a8229f

The open-access MAF lists 123 somatic variants for this specimen: 43 protein-altering or splice-affecting, 19 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 34, Missense Mutation 33, Silent 19, Intron 14, 5'UTR 5, Frame Shift Del 4, 5'Flank 4, RNA 3, Splice Site 3, Frame Shift Ins 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 38/173 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs121913236, CM070964, COSV55526911, COSV55779357; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.8527G>A p.A2843T | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV99593037; called by muse, mutect2, varscan2
- FASTKD1 | c.1188dup p.A397Cfs*4 | Frame Shift Ins (INS) | VAF 17/75 reads (23%) | catalogued as rs770112643; called by mutect2, pindel, varscan2
- KIAA1549 | c.2122A>G p.M708V | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1308287799; called by muse, mutect2, varscan2
- KIF21B | c.2824C>T p.R942W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754180658, COSV59751648; called by muse, mutect2, varscan2
- SDK1 | c.1055C>A p.P352Q | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67378325; called by muse, mutect2
- TMPRSS4 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 245/388 reads (63%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs781599975, COSV71110438; called by muse, mutect2, varscan2
- TRAV13-1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 74/81 reads (91%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751141340; called by muse, mutect2, varscan2
- TRAV19 | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs762651432; called by muse, mutect2, varscan2
- TRIM24 | c.2754T>A p.H918Q (on ENST00000343526 / NM_015905.3; = p.H884Q on NM_003852.4) | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58972047; called by muse, mutect2, varscan2
- ANKRD11 | c.491_492del p.R164Kfs*46 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | called by pindel, varscan2
- ARHGDIB | c.530T>C p.F177S | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- BCAS1 | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.17); called by muse, mutect2
- BHLHE41 | c.1404C>A p.S468R | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BTBD11 | c.1720T>G p.F574V (on ENST00000280758 / NM_001018072.2; = p.F111V on NM_001017523.2) | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CATSPERD | c.1586T>C p.I529T | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- CFAP47 | c.3971_3975del p.V1324Gfs*26 | Frame Shift Del (DEL) | VAF 36/38 reads (95%) | called by mutect2, pindel
- CHD9 | c.2113-5C>A | Splice Region (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- CKAP2L | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 91/259 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CWC25 | c.567T>G p.H189Q | Missense Mutation (SNP) | VAF 83/152 reads (55%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- EEF1A2 | c.232T>C p.W78R | Missense Mutation (SNP) | VAF 104/306 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GARNL3 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GCGR | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- GLG1 | c.2436+2T>C p.X812_splice | Splice Site (SNP) | VAF 39/100 reads (39%) | called by muse, mutect2, varscan2
- GPR37 | c.1294T>G p.Y432D | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- H2BC10 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- HIRA | c.1007+1G>T p.X336_splice | Splice Site (SNP) | VAF 41/111 reads (37%) | called by muse, mutect2, varscan2
- IRX3 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LIMD1 | c.10T>A p.Y4N | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- MYO18B | c.1570T>A p.F524I | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOSTRIN | c.1382A>G p.K461R (on ENST00000317647 / NM_001039724.4; = p.K383R on NM_052946.3) | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- OAZ1 | c.189_198del p.P64Afs*9 | Frame Shift Del (DEL) | VAF 16/106 reads (15%) | called by mutect2, pindel, varscan2
- PARP9 | c.2522A>T p.Q841L | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.005); called by mutect2, varscan2
- PBX3 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 86/224 reads (38%) | called by muse, varscan2
- PCDHA13 | c.1061C>G p.S354C | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PHEX | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKN1 | c.2608A>C p.K870Q | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PRKAR1A | c.861A>C p.E287D | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RBM12 | c.485T>C p.M162T | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SEMA6C | c.1420T>A p.Y474N | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC20A2 | c.1928T>C p.L643P | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- UGT2B7 | c.1566del p.A523Qfs*11 | Frame Shift Del (DEL) | VAF 123/324 reads (38%) | called by mutect2, pindel, varscan2
- USP20 | c.81+1G>A p.X27_splice | Splice Site (SNP) | VAF 86/244 reads (35%) | called by muse, mutect2, varscan2
- ABCA1 | c.3918C>T p.D1306= | Silent (SNP) | VAF 39/303 reads (13%) | catalogued as rs1255574007; called by muse, mutect2, varscan2
- APAF1 | c.1299T>C p.F433= (on ENST00000551964 / NM_181861.2; = p.F422= on NM_001160.3) | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs773139246; called by muse, mutect2, varscan2
- BDP1 | c.6681T>C p.S2227= | Silent (SNP) | VAF 48/123 reads (39%) | called by muse, mutect2, varscan2
- FAIM2 | c.900C>T p.I300= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as rs1364331314; called by muse, mutect2, varscan2
- FAM205A | c.2823C>T p.L941= | Silent (SNP) | VAF 98/453 reads (22%) | called by muse, mutect2, varscan2
- IGHV3-13 | c.66G>A p.Q22= | Silent (SNP) | VAF 34/41 reads (83%) | catalogued as rs376321151; called by muse, mutect2, varscan2
- KCND2 | c.450C>T p.D150= | Silent (SNP) | VAF 7/138 reads (5%) | catalogued as COSV58591656; called by muse, mutect2
- LAX1 | c.639C>T p.S213= | Silent (SNP) | VAF 83/137 reads (61%) | called by muse, mutect2, varscan2
- MAGEB10 | c.738G>A p.K246= | Silent (SNP) | VAF 25/34 reads (74%) | called by muse, mutect2, varscan2
- MEF2C | c.114G>A p.L38= | Silent (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- MYH4 | c.1485C>T p.H495= | Silent (SNP) | VAF 46/101 reads (46%) | called by muse, mutect2, varscan2
- PHF1 | c.1482T>G p.T494= | Silent (SNP) | VAF 132/406 reads (33%) | called by muse, mutect2, varscan2
- PODNL1 | c.414G>A p.R138= | Silent (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- PRDM9 | c.516G>A p.R172= | Silent (SNP) | VAF 17/151 reads (11%) | catalogued as COSV57005436; called by muse, mutect2, varscan2
- SOX14 | c.465G>T p.V155= | Silent (SNP) | VAF 34/170 reads (20%) | called by muse, mutect2, varscan2
- TEX15 | c.3174T>C p.Y1058= (on ENST00000256246; = p.Y1441= on NM_001350162.2) | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- TOMM70 | c.411T>C p.Y137= | Silent (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- VAV2 | c.2283C>T p.T761= (on ENST00000371850 / NM_001134398.2; = p.T751= on NM_003371.4) | Silent (SNP) | VAF 68/175 reads (39%) | catalogued as COSV100896039; called by muse, mutect2, varscan2
- ZNF138 | c.192G>A p.V64= | Silent (SNP) | VAF 304/509 reads (60%) | called by muse, mutect2, varscan2
- AC103993.1 | n.1031G>A | RNA (SNP) | VAF 34/60 reads (57%) | called by muse, mutect2, varscan2
- AC134878.2 | n.930C>T | RNA (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- ADGRL2 | c.*406del | 3'UTR (DEL) | VAF 30/41 reads (73%) | called by mutect2, pindel, varscan2
- AP3B2 | c.*215C>T | 3'UTR (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.3976+84A>G | Intron (SNP) | VAF 6/34 reads (18%) | catalogued as rs1349630724; called by mutect2, varscan2
- ATAD2B | c.*1554G>A | 3'UTR (SNP) | VAF 33/108 reads (31%) | catalogued as rs1453161839; called by muse, mutect2, varscan2
- C19orf54 | c.392+148del | Intron (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel*, varscan2*
- CACNA1C | chr12:2053445 C>T | 5'Flank (SNP) | VAF 4/76 reads (5%) | catalogued as rs1268937124; called by muse, mutect2
- CMTM7 | c.-7C>T | 5'UTR (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- COL28A1 | c.*69A>G | 3'UTR (SNP) | VAF 86/274 reads (31%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.*120G>A | 3'UTR (SNP) | VAF 13/52 reads (25%) | catalogued as rs547688649; called by muse, mutect2, varscan2
- DCP2 | c.*2245dup | 3'UTR (INS) | VAF 12/93 reads (13%) | called by mutect2, pindel, varscan2
- EGR1 | c.-26C>G | 5'UTR (SNP) | VAF 33/57 reads (58%) | called by muse, mutect2, varscan2
- EHD4 | c.*1044G>A | 3'UTR (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- ELMOD3 | c.*562G>A | 3'UTR (SNP) | VAF 17/232 reads (7%) | called by muse, mutect2
- EXOC6B | c.1980+773C>T | Intron (SNP) | VAF 59/84 reads (70%) | called by muse, mutect2, varscan2
- EYA2 | c.979-2158C>T | Intron (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- GABRA4 | c.*3697G>T | 3'UTR (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- GABRG2 | c.*915G>T | 3'UTR (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- GALNT7 | c.*395T>G | 3'UTR (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- GOT2 | c.*885G>A | 3'UTR (SNP) | VAF 84/154 reads (55%) | catalogued as rs1170107081; called by muse, mutect2, varscan2
- GPR173 | c.*190A>T | 3'UTR (SNP) | VAF 17/19 reads (89%) | called by muse, mutect2, varscan2
- H2AC14 | c.*9T>G | 3'UTR (SNP) | VAF 103/249 reads (41%) | called by muse, mutect2, varscan2
- HEXA | chr15:72376340 G>A | 5'Flank (SNP) | VAF 29/221 reads (13%) | called by muse, mutect2, varscan2
- HOPX | c.*597A>G | 3'UTR (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- HPGD | chr4:174522525 G>A | 5'Flank (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- IMMP2L | c.305+864G>T | Intron (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- KCTD15 | c.693+84G>A | Intron (SNP) | VAF 24/69 reads (35%) | catalogued as COSV52292076; called by muse, mutect2, varscan2
- KLHL13 | c.99-1189C>A | Intron (SNP) | VAF 34/36 reads (94%) | called by muse, mutect2, varscan2
- LIFR | c.*4308A>C | 3'UTR (SNP) | VAF 107/163 reads (66%) | called by muse, mutect2, varscan2
- LINC01276 | n.479G>A | RNA (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- MARCKS | c.-323_-308delinsAA | 5'UTR (DEL) | VAF 28/43 reads (65%) | called by pindel, varscan2*
- MARCKSL1 | c.*646T>C | 3'UTR (SNP) | VAF 7/45 reads (16%) | catalogued as rs1448348317; called by muse, mutect2, varscan2
- NDRG3 | c.*828G>A | 3'UTR (SNP) | VAF 103/167 reads (62%) | called by muse, mutect2, varscan2
- NRK | c.*1097del | 3'UTR (DEL) | VAF 26/30 reads (87%) | catalogued as rs1012867736; called by mutect2, varscan2
- NRXN1 | c.832+3238T>A | Intron (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- OAS2 | c.448+1180G>A | Intron (SNP) | VAF 45/85 reads (53%) | catalogued as rs1022789349; called by muse, mutect2, varscan2
- PFKM | c.*144G>A | 3'UTR (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- PGM2L1 | c.111+29C>T | Intron (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2
- PLAAT3 | chr11:63614422 T>C | 5'Flank (SNP) | VAF 12/74 reads (16%) | called by mutect2, varscan2
- POM121L12 | c.*266G>A | 3'UTR (SNP) | VAF 30/113 reads (27%) | catalogued as rs921229525; called by muse, mutect2, varscan2
- PTGFR | c.*509G>A | 3'UTR (SNP) | VAF 22/70 reads (31%) | catalogued as rs569401739; called by muse, mutect2, varscan2
- RAB1A | c.*93C>G | 3'UTR (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- RBM25 | c.867+552G>A | Intron (SNP) | VAF 71/118 reads (60%) | called by muse, mutect2, varscan2
- RDH16 | c.-741C>A | 5'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- RPS17 | c.*756T>C | 3'UTR (SNP) | VAF 162/617 reads (26%) | called by muse, mutect2, varscan2
- SCN11A | c.4327+428C>T | Intron (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- SEC62 | c.*750C>G | 3'UTR (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- SLC38A7 | c.*461A>G | 3'UTR (SNP) | VAF 42/99 reads (42%) | catalogued as rs879206479; called by muse, mutect2, varscan2
- SMYD3 | c.531+1138G>A | Intron (SNP) | VAF 8/45 reads (18%) | catalogued as rs1273255762; called by muse, mutect2, varscan2
- SRF | c.*977C>T | 3'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- STT3B | c.*1512A>C | 3'UTR (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- TAF1L | c.*277G>T | 3'UTR (SNP) | VAF 12/23 reads (52%) | called by muse, varscan2
- TFCP2L1 | c.*5310G>A | 3'UTR (SNP) | VAF 91/379 reads (24%) | called by muse, mutect2, varscan2
- TRPV5 | c.*293C>A | 3'UTR (SNP) | VAF 36/140 reads (26%) | called by muse, mutect2, varscan2
- TSPAN19 | c.679-83T>C | Intron (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*286C>T | 3'UTR (SNP) | VAF 42/83 reads (51%) | called by muse, mutect2, varscan2
- UHMK1 | c.-165G>A | 5'UTR (SNP) | VAF 20/111 reads (18%) | catalogued as rs1557937611; called by muse, mutect2, varscan2
- VPS26C | chr21:37221435 A>G | 3'Flank (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- XBP1 | c.*8del | 3'UTR (DEL) | VAF 52/216 reads (24%) | called by mutect2, pindel, varscan2
- ZNF268 | c.*412G>T | 3'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
